Gene-level copy-number profile of tumor specimen TCGA-CQ-A4CG-01A from TCGA case TCGA-CQ-A4CG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 78.4 years (28,637 days).
Specimen TCGA-CQ-A4CG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.b0333339-f80b-473f-9311-e111c7dce1e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CQ-A4CG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1083fdfb-ec20-4095-a46c-136e92fce7d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 977; copy number 2: 46,430; copy number 3: 7,463; copy number 4: 4,920; copy number 5: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CQ-A4CG-01A-11D-A25X-01): tumor purity 0.75, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:135,343,249–136,124,363, 25 genes, copy number 5: C9orf62, AL353615.1, SOCS5P2, PPP1R26-AS1, PPP1R26, C9orf116, MRPS2, AL161452.1, LCN1, OBP2A, PAEP, LINC01502, PAEPP1, AL354761.1, GLT6D1, LCN9, SOHLH1, KCNT1, CAMSAP1, AL355574.1, UBAC1, NACC2, LINC02846, TMEM250, AL138781.1.

Autosomal genes at a single copy (total copy number 1): 977. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
